Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A8OX, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A8OX-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB Age Gender: F

Ref#: Hosp#: Provider Group:

Date of Service: Date Received:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

LEFT KIDNEY, NEPHRECTOMY:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- Fuhrman grade 3.
- Tumor size: 3.3 cm in greatest dimension.
- Tumor confined to the kidney.
- MARGINS NEGATIVE FOR TUMOR.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Histologic type and grade: Renal cell carcinoma, clear cell type.

Primary tumor: pT1.

Regional lymph nodes: pNX.

Distant metastasis: Not applicable.

Margin status: R0.

Pathologic stage: Stage I.

Lymphovascular invasion: Not identified.

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, February 2011.

ICD-O-3
Carcinoma, clear cell 8510/3
Site ① Kidney NOS C64.9
J 24/11/14

Case #

Printed

Page 1

This report continues... (FINAL)

Patient Name -

[page 2 of 3]
Patient:

Case #:

Procedure:

Specimen type:

Specimen laterality:

TUMOR FEATURES:

Tumor size:

Tumor focality:

Histologic type:

Histologic grade (Fuhrman nuclear grade):

Sarcomatoid features:

Macroscopic extent of tumor:

Microscopic tumor extension:

LYMPH NODES:

MARGIN EVALUATION:

Distance to closest margin:

PATHOLOGIC TUMOR STAGING:

Primary tumor:

Regional lymph nodes:

Distant metastasis:

Margin status:

Pathologic stage:

Pathologic findings in non-neoplastic kidney:

Nephrectomy.

Kidney and proximal ureter.

Left.

3.3 cm.

Single focus.

Renal cell carcinoma, clear cell (conventional) type.

3.

Not present.

Tumor confined within the kidney.

Tumor confined within the kidney.

No lymph nodes identified.

2.0 cm from the hilar margin.

pT1.

pNX.

Not applicable.

Negative.

I.

Mild compressive effect adjacent to tumor.

Signed by

Source of Specimen:

Case #

Printed

Page 2

This report continues... (FINAL)

MR No.

Patient Name

[page 3 of 3]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Kidney;Left

Clinical History/Operative Dx:

Renal mass

Gross Description:

The specimen is labeled left kidney and is received without fixative. It consists of a nephrectomy specimen which weighs 226 grams. The kidney measures 12 cm from superior to inferior, 8 cm from medial to lateral, and 4.5 cm from anterior to posterior. There is no grossly identifiable adrenal gland tissue. Thin and delicate membranous tissue is present along the anterior surface and consistent with Gerota's fashion. It is inked black. At the hilum the renal artery and renal vein are identified. The vessels are opened without gross evidence of intraluminal tumor. Extending from the hilum of the kidney inferiorly is a 6.5 cm segment of thin and delicate ureter which is 0.3 cm in diameter. The ureter is open and the urothelium is smooth and tan-white. The central posterior surface of the kidney is covered by a thin layer of fatty and smooth membranous tissue with a palpable mass bulging outward from the posterior surface. This area is inked green. On sectioning there is a central posterior circumscribed tumor mass within the kidney which measures 3.3 x 2.5 x 2.5 cm. It is separated from the posterior surface of the kidney by a thin layer of freely movable membranous tissue. It is 2 cm from the renal hilum and abuts but does not appear to grossly invade the renal hilar adipose tissue. It does not appear to involve the upper pole calix or the lower pole calix. Representative sections of the tumor, which has a variegated yellow-tan to dark red appearance are obtained for research purposes. Following partial fixation representative sections are submitted. Section summary: A1) surgical margin, renal artery, renal vein and ureter, A2) additional sections of ureter and ureteral pelvic junction, A3) Gerota's fascia, A4) posterior surface of kidney with underlying tumor, A5-A6) additional representative sections of tumor, A7) tumor and closest approach to renal pelvis, A8) uninvolved kidney.

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Source: NCI Genomic Data Commons file 46a436ce-71e3-46f7-8345-8a829a5f8bf3 (TCGA-A3-A8OX.9FB77460-D783-4FA4-874F-634CC998B49B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).